TCGA case TCGA-C5-A1ML — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/374f614a-bcd1-4283-ac6f-fc27ddc79987

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 636 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 49.5 years (18,067 days); Year of diagnosis: 2005; Method of diagnosis: Biopsy; FIGO stage: Stage IB2; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 68 days; Days to treatment end: 111 days; Treatment dose: 5,040 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (4 entries)
- Day 37 (preoperative): Days to imaging: 37 days; Imaging type: PET; Imaging anatomic site: Cervix Uteri; Imaging suv: 14.46.
- Day 37 (preoperative): Days to imaging: 37 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Days to follow up: 636 days (1.7 years); Disease response: With Tumor.
- Imaging type: MRI; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease; Timepoint: Preoperative.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV16].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 120 kg.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 37.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1ML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-C5-A1ML-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-C5-A1ML-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 2; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other).
- Diagnostic mri result outcomes: Lymph nodes supraclavicular: Extra-Pelvic Metastatic Disease Present.
- Diagnostic ct result outcomes: Ct scan preop results: Extra-Pelvic Metastatic Disease Present.
- Human papillomavirus types: HPV types positive: HPV 16.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; New tumor event diagnosis indicator: No.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 636 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 636 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 636 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1ML-01A-11D-A14V-01): tumor purity 0.79, ploidy 3.82, whole-genome doublings 1.
